Somatic mutation profile of tumor specimen TCGA-FG-5965-01B (aliquot TCGA-FG-5965-01B-11D-1893-08) from TCGA case TCGA-FG-5965, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 39.0 years (14,249 days).
Specimen TCGA-FG-5965-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41e173d2-a5e8-4e56-a0b6-d9f5aacbf90c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-5965-10A (Blood Derived Normal), aliquot TCGA-FG-5965-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/42c97e90-d1f1-4269-8097-5738a0336cb7

The open-access MAF lists 46 somatic variants for this specimen: 34 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 10, Splice Site 2, 3'Flank 1, Frame Shift Del 1, Intron 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 25/94 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- OTX2 | c.235G>A p.E79K (on ENST00000408990 / NM_172337.3; = p.E87K on NM_021728.4) | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs786205224, CM1411529, COSV59765795; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 24/32 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRE3 | c.1339A>G p.T447A | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV53729639; called by muse, mutect2, varscan2
- ANO2 | c.2378C>A p.T793N (on ENST00000356134 / NM_001278597.3; = p.T797N on NM_001278596.3) | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as COSV59015876; called by muse, mutect2, varscan2
- ATRX | c.4838T>A p.L1613* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV64874373, COSV64883894; called by muse, mutect2, varscan2
- BEND2 | c.1982-2A>T p.X661_splice | Splice Site (SNP) | VAF 18/86 reads (21%) | catalogued as COSV66215492; called by muse, mutect2, varscan2
- BVES | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 51/282 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375067894, COSV100115092, COSV58947214; called by muse, mutect2, varscan2
- CACNG7 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.115); catalogued as COSV55813839; called by muse, mutect2
- CAMTA1 | c.1101C>G p.N367K | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.257); catalogued as COSV57892728; called by muse, mutect2, varscan2
- CPS1 | c.3927+2T>A p.X1309_splice | Splice Site (SNP) | VAF 39/98 reads (40%) | catalogued as COSV51806538; called by muse, mutect2, varscan2
- DGAT2L6 | c.857T>A p.V286D | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60717462; called by muse, mutect2, varscan2
- EPCAM | c.913A>G p.M305V | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as rs753121449, COSV55392790; called by muse, mutect2, varscan2
- EYA3 | c.604A>G p.I202V | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.707); catalogued as rs755186429, COSV65816241; called by muse, mutect2, varscan2
- GPKOW | c.997C>T p.R333W | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1372784411, COSV50242378; called by muse, mutect2, varscan2
- GPR174 | c.984G>C p.M328I | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV52131987; called by muse, mutect2, varscan2
- HDAC6 | c.3376G>T p.G1126C | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV57806582; called by muse, mutect2, varscan2
- KANK2 | c.310G>A p.G104S | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.114); catalogued as rs147297854; called by muse, mutect2, varscan2
- LPL | c.642A>C p.R214S | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60930776; called by muse, mutect2, varscan2
- LTBR | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 36/349 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.175); catalogued as COSV57438648; called by muse, mutect2, varscan2
- MED15 | c.1873G>A p.V625I (on ENST00000263205 / NM_001003891.3; = p.V585I on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.241); catalogued as rs1018320157, COSV53028325; called by muse, mutect2, varscan2
- MS4A1 | c.242G>A p.C81Y | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.883); catalogued as rs1565194450, COSV61941950; called by muse, mutect2, varscan2
- OBSCN | c.13321G>A p.A4441T | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1299532747, COSV52760315, COSV99478362; called by muse, mutect2, varscan2
- OR51G1 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.434); catalogued as rs776718496, COSV58968867; called by muse, mutect2, varscan2
- PDIA6 | c.982A>G p.K328E | Missense Mutation (SNP) | VAF 99/529 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55350170; called by muse, mutect2, varscan2
- QKI | c.659C>G p.A220G | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.97); catalogued as COSV51691861; called by muse, mutect2, varscan2
- RP1L1 | c.6544G>A p.A2182T | Missense Mutation (SNP) | VAF 76/485 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.021); catalogued as rs765192713, COSV66753810; called by muse, mutect2, varscan2
- SHC1 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.952); catalogued as COSV58316094; called by muse, mutect2, varscan2
- TFE3 | c.1445dup p.P483Tfs*138 | Frame Shift Ins (INS) | VAF 54/186 reads (29%) | catalogued as rs782753958; called by mutect2, varscan2
- THSD7B | c.4687G>A p.V1563I (on ENST00000272643; = p.V1561I on NM_001316349.2) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs372041308, COSV99744669; called by muse, mutect2, varscan2
- VPS13B | c.3271A>G p.I1091V | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.952); catalogued as rs780930460, COSV62138195; called by muse, mutect2
- WDR11 | c.3088G>C p.D1030H | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54787134; called by muse, mutect2
- XIAP | c.584G>C p.G195A | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV63022067; called by muse, mutect2, varscan2
- PPP1R10 | c.157del p.I53Ffs*27 | Frame Shift Del (DEL) | VAF 35/124 reads (28%) | called by mutect2, pindel, varscan2
- ADAM20 | c.30C>T p.I10= | Silent (SNP) | VAF 52/132 reads (39%) | catalogued as COSV56454588; called by muse, mutect2, varscan2
- APCS | c.45G>A p.L15= | Silent (SNP) | VAF 18/127 reads (14%) | catalogued as rs994697399, COSV54817748; called by muse, mutect2, varscan2
- CACNA2D2 | c.861G>A p.S287= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as rs771844125, COSV56559907; called by muse, mutect2, varscan2
- FGD4 | c.2037C>G p.A679= | Silent (SNP) | VAF 17/92 reads (18%) | catalogued as COSV56782472; called by muse, mutect2, varscan2
- HS3ST4 | c.852T>A p.I284= | Silent (SNP) | VAF 37/220 reads (17%) | catalogued as COSV58809397; called by muse, mutect2, varscan2
- MTO1 | c.774G>A p.P258= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as rs748667460, COSV64773428; called by muse, mutect2, varscan2
- OSTF1 | c.477T>G p.L159= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as COSV60547069; called by muse, mutect2, varscan2
- PIBF1 | c.1785A>G p.L595= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as COSV58321947; called by muse, mutect2, varscan2
- RPS6KA6 | c.333T>C p.S111= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV53118339; called by muse, mutect2, varscan2
- TRH | c.606C>T p.A202= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV57014776; called by muse, mutect2, varscan2
- FAM153CP | chr5:178056118 G>A | 3'Flank (SNP) | VAF 17/46 reads (37%) | catalogued as rs1047231505; called by muse, mutect2, varscan2
- MACROD2 | c.418+165024G>A | Intron (SNP) | VAF 8/34 reads (24%) | catalogued as rs199910638, COSV53965976; called by muse, mutect2, varscan2
